Surgical pathology report (de-identified scan), TCGA case TCGA-05-5715, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-5715-01A (Primary Tumor).

Diagnosis:

Intermediate to peripheral bronchopulmonary, well differentiated mixed adenocarcinoma (G1) of the left upper lobe of the lung mainly localized in S1.

TNM classification (UICC, 7th ed., 2009) on the basis of these findings: pT2a pN0 L0 V0 R0, stage IB.

C34.1, M8255/3.

Remark:

The carcinoma shows quantities of predominantly luminal mucus and a bronchioloalveolar pattern of spread with a partly pseudopapillary structure here and a small acinar and solid component. The overgrown partially resected material from S6 shows initial infiltration. The resection surface, the resection margins of the bronchus and vessels (sample 1) and the lymph nodes of samples 2 to 8 are tumor-free.

Source: NCI Genomic Data Commons file 78abd347-1c3c-449e-b2a9-6d923eed15cd (TCGA-05-5715.B764FCED-B638-48C6-82A6-4D3663BB2168.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).